Somatic mutation profile of tumor specimen TCGA-E8-A413-01A (aliquot TCGA-E8-A413-01A-21D-A23M-08) from TCGA case TCGA-E8-A413, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.1 years (13,909 days).
Specimen TCGA-E8-A413-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86c8d5ee-7d40-4b96-83f9-f5ea858c1602.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A413-10A (Blood Derived Normal), aliquot TCGA-E8-A413-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d26799ef-e08d-4895-a583-3118ae868207

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FDX2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1200342393; called by muse, mutect2
- SLC28A1 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV54476961; called by muse, mutect2, varscan2
- WLS | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.11); called by muse, mutect2
- NAA16 | c.2541T>G p.P847= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as COSV65127615; called by muse, mutect2, varscan2
- ZC3H13 | c.1380T>C p.D460= | Silent (SNP) | VAF 11/242 reads (5%) | catalogued as COSV54448708; called by muse, mutect2
- MIR520B | n.12G>A | RNA (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
